Surgical pathology report (de-identified scan), TCGA case TCGA-D3-A1Q3, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site MD Anderson, specimen TCGA-D3-A1Q3-06A (Metastatic).

[page 1 of 3]
**** Case imported from legacy computer system. The format of this report does not match the original case. ****

**** For cases prior to , the section "SPECIMEN" may have been added. ****

DIAGNOSIS

- (A) SKIN LEFT HEEL:
MULTIFOCAL MALIGNANT MELANOMA INVOLVING JUNCTION AND DERMIS AND
FOCALLY EXTENDING INTO SUBCUTANEOUS TISSUE.
FOCUS OF MALIGNANT MELANOMA AT 2-3 O'CLOCK MARGIN.
- (B) DISTAL/POSTERIOR CALCANEUS:
No tumor seen.
- (C) LEFT CLOQUET LYMPH NODE:
METASTATIC MALIGNANT MELANOMA.
- (D) LEFT SPERMATIC CORD TISSUE:
Fibrous tissue with foreign material.
- (E) LEFT SUPERFICIAL GROIN TISSUE:
**METASTATIC MALIGNANT MELANOMA IN FOUR OF FIVE LYMPH NODES (LARGEST
NODE GROSSLY 5.1 X 4.7 CM).**
EXTRANODAL EXTENSION IDENTIFIED.
- (F) ADDITIONAL SUPEROMEDIAL MARGIN LEFT HEEL:
MALIGNANT MELANOMA IN DERMIS AT MARGIN.
- (G) NEW 3 O'CLOCK MARGIN:
MALIGNANT MELANOMA IN DERMIS, MARGIN FREE.
- (H) ADDITIONAL INFERIOR MEDIAL MARGIN:
No tumor seen.
- (I) LEFT COMMON ILIAC NODE:
Lymph node, no tumor seen.
- (J) INTERNAL AND EXTERNAL ILIAC CONTENTS:
METASTATIC MALIGNANT MELANOMA IN TWO OF THREE LYMPH NODES.
- (K) LEFT OBTURATOR CONTENTS:
ONE LYMPH NODE, WITH METASTATIC MALIGNANT MELANOMA.

TIPTA Discrepancy		☒

1CΔ-0-3
Melanoma, NOS 8720/3
S. He. lymph node, NOS C77.4
3/15/11 per

Entire report and diagnosis completed by: , MD
Report released by:

GROSS DESCRIPTION

(A) METASTATIC MELANOMA, LEFT HEEL - A 9.0 x 6.0 x 1.3 cm excisional segment of skin and subcutaneous tissue. The specimen is oriented by the surgeon. A short suture designates the superior margin and a long suture designates the medial margin. A central, 4.5 x 4.0 cm, area of scar is present. Just lateral to the scar is a 1.5 x 1.0 cm, ulcerating, whitish nodule. Approximately 0.3 cm from this lesion is another 0.6 cm ulcer with granulation tissue. This small ulcer is 1.0 cm from the nearest lateral margin. Approximately 0.8 cm from the superomedial margin is a 0.2 cm incision with a suture. No other lesions are identified on the skin surface. On the deep aspect of the excision, is a 2.5 x 1.5 cm area that does not represent the true margin as the surgeon submitted a separate deep margin in this area. This area is inked green.
A separate 0.6 cm, tan-brown nodule is identified superior and lateral to the main satellite nodule (1.5 x 1.0 x 0.6 cm) The satellite nodule is 0.5 from the deep margin.
INK CODE: Blue - superior. Orange - inferior. Green - deep (not true margin).

Sample

[page 2 of 3]
SECTION CODE: A1, A2, 1 o'clock and 2 o'clock position shave margin; A3, A4, 9 and 10 o'clock shave margin, respectively; A5, 3 o'clock; A6, 4 o'clock; A7, 5 o'clock; A8, 6 o'clock; A9, 7 o'clock; A10, 8 o'clock; A11, 11 o'clock; A12, 12 o'clock; A13, A14, small ulcer adjacent to satellite nodule; A15, A16, satellite nodule lateral to scar; A17, smaller tan-brown nodule superior and lateral to main satellite nodule; A18-A29, representative sections of scar from lateral to medial; A30, representative of incision with suture near 3 o'clock position.

*FS/DX: METASTATIC MELANOMA AT SUPERIOR MEDIAL MARGIN (A2).

(B) DISTAL/POSTERIOR CALCANEUS - A 2.0 x 1.5 x 0.2 cm irregular piece of tan-pink soft tissue with no lesions identified.

INK CODE: Blue - lateral; orange - medial.

SECTION CODE: Entire tissue submitted from inferior to superior in B1-B3.

*FS/DX: NEGATIVE FOR TUMOR.

(C) LEFT CLOQUET LYMPH NODE - A single dark-brown lymph node, 3.5 x 1.0 x 0.7

cm. Grossly, the lymph node is fatty and does not appear to be involved by tumor. The entire lymph node is sectioned and submitted in C1-C5.

*FS/DX: ONE LYMPH NODE WITH METASTATIC MELANOMA.

(D) LEFT SPERMATIC CORD TISSUE - A 1.2 x 1.0 x 0.5 cm segment of tan-white tissue, with mesh material present within the tissue. The specimen is bisected

and submitted entirely for frozen section as D.

*FS/DX: FIBROCONNECTIVE TISSUE WITH FOREIGN MATERIAL. NEGATIVE FOR TUMOR.

(E) LEFT SUPERFICIAL GROIN - An irregular, lobulated, red-tan portion of adipose tissue (27.3 x 10.8 x 2.5 cm). Four lymph nodes are identified ranging from 0.6 x 0.6 x 0.4 cm to 1.5 x 1.5 x 0.6 cm. Also present is a 4.7 x 5.1 x 1.8 cm pigmented matted lymph node.

SECTION CODE: E1-E2, one lymph node trisected; E3-E4, one lymph node trisected; E5, two lymph nodes; E6-E10, representative section of pigmented matted lymph node.

(F) LEFT HEEL, ADDITIONAL SUPEROMEDIAL MARGIN - A skin ellipse, 3.0 x 0.8 x 0.6 cm. No lesion is identified. The true margin is inked blue by the surgeon.

INK CODE: Blue - true margin.

SECTION CODE: F1-F3, entire tissue from 1 o'clock to 3 o'clock, sequentially, perpendicular.

*FS/DX: METASTATIC MELANOMA PRESENT AT INKED MARGIN AT 3 O'CLOCK.

(G) NEW 3 O'CLOCK MARGIN, LEFT FOOT, NEW MARGIN MARKED WITH PEN - A piece of skin, 1.8 x 1.0 x 0.4 cm. One edge of the specimen is marked blue. This edge

is re-inked with blue ink. The specimen is entirely submitted with perpendicular sections to the inked margin for frozen section in G1-G3.

*FS/DX: 2.5 MM MELANOMA FOCUS, MARGIN NEGATIVE FOR MELANOMA.

(H) ADDITIONAL INFERIOR MEDIAL MARGIN - A 2.9 x 0.8 x 0.3 cm irregular segment of skin. The specimen is not oriented. No lesion is identified.

INK CODE: Blue-deep and peripheral margins.

SECTION CODE: H1, H2, entire skin serially sectioned.

(I) LEFT COMMON ILIAC NODE - A single tan-brown lymph node 1.2 x 0.5 x 0.2 cm. Grossly the lymph node does not appear to be involved by tumor. Bisected

and submitted entirely in I.

(J) LEFT INTERNAL AND EXTERNAL ILIAC CONTENTS - Multiple irregular fragments of pink-tan adipose tissue (8.6 x 6.1 x 1.7 cm) in aggregate. Three lymph nodes are identified ranging from 0.6 x 0.6 x 0.3 cm to 6.1 x 3.1 x 0.4 cm.

SECTION CODE: J1, one lymph node; J2, one lymph node; J3-J10, one lymph node serially sectioned.

(K) LEFT OBTURATOR CONTENTS - Multiple irregular fragments of pink-tan

[page 3 of 3]
adipose tissue (7.3 x 6.1 x 1.3 cm in aggregate). A single lymph node is identified (4.2 x 2.1 x 0.3 cm) and submitted in K1-K4.

SNOMED CODES

-----END OF REPORT-----

Source: NCI Genomic Data Commons file 14057f40-7b3c-4706-b9f6-49ea8e9ef281 (TCGA-D3-A1Q3.FCC5E470-C979-4265-917E-DD6C25B19606.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).